Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AAC4, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AAC4-01A (Primary Tumor).

[page 1 of 2]
[Redacted]

Printed

DOB: [Redacted]

Sex: M

Ref. by [Redacted]
Collection Date: [Redacted]

[Redacted]

CYTOLOGY: PLEURAL FLUID

CLINICAL HISTORY:

Past asbestos exposure. Moderate left pleural effusion.

SPECIMEN:

50ml of clear yellow fluid received.

MICROSCOPIC:

Smears and cell block preparation show numerous aggregates of mesothelial cells with papillary-like formations and focal stromal or fibrovascular cores. The nuclei show minimal variability with well defined nuclear membranes and focal small nucleoli. The groups are predominantly small to moderate size. There are background macrophages and mononuclear cells identified. No overt high-grade malignant features seen. The fluid however is highly cellular.

CONCLUSION:

Pleural fluid: Highly cellular fluid showing features highly suspicious of malignant mesothelioma. The differential diagnosis includes a florid atypical hyperplasia. Further immunoperoxidase studies will be performed and a separate report issued. The cell block shows similar features.

Pathologist:

M

Normal File
Notes Required
Patient Notified
Patient Will Call
Make Appointment
Collect Prescription
On Correlation Treatment
Check with Doctor

Confidentiality: This document is confidential. If you are not the intended recipient you must not read, copy, distribute or act in reliance on it. If you have received this document in error please notify us immediately and destroy the original message.

ICD-O-3
Mesothelioma, malignant NOS
9050/3
Site: Pleura NOS C38.4
Q40 1/29/14

[page 2 of 2]
DOB: 	Sex: M	Ref. by Collection Date: 	Printed
---	--------	--	--

SUPPLEMENTARY REPORT

Immunoperoxidase stains show CK7 positive. EMA positive with rim positivity. CD15 negative. Calretinin strongly positive. CK5/6 strongly positive. CK20 equivocal weak positive. CEA negative.

CONCLUSION:

These findings and the smears have been reviewed by another pathologist and the findings are in keeping with a diagnosis of MALIGNANT MESOTHELIOMA.

Pathologist:

Normal File
Notes Required
Patient Notified
Patient Will Call
Make Appointment
Collect Prescription
On Correct Treatment
Check with Doctor

M

Confidentiality: This document is confidential. If you are not the intended recipient you must not read, copy, distribute or act in reliance on it. If you have received this document in error please notify us immediately and destroy the original message.

	Yes	No
Critera		✓
PIAA Discrepancy		✓
Timing/Malignancy History	SKIN	
Qual/Syncronous Primary Nodules	DISQUALIFIED	

Source: NCI Genomic Data Commons file d2bf0bbd-96c5-49af-9879-cf517f9b8c04 (TCGA-UD-AAC4.8FDC47D6-2DD0-428A-96C1-C6F70D67A07C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).